MMRF case MMRF_2574 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6da0969c-8037-4e01-9ba3-3412a41d67ef

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 475 days (1.3 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.5 years (27,213 days); ISS stage: II; Days to last known disease status: 475 days (1.3 years); Days to last follow up: 475 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 89 days; Days to treatment end: 89 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 90 days; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 445 days (1.2 years); Days to treatment end: 446 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 475.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 267 mg/dL; Immunoglobulin G 6.85 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.8 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 106 (ECOG 1): Hemoglobin 5.64 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 45 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.65 mmol/L; Albumin 27 g/L; Total Protein 4.8 g/dL; Glucose 5.67 mmol/L.
- Day 172 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.921 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.822 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.83 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 270 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.916 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.995 mg/dL; Immunoglobulin G 4.74 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 5.6 g/dL; Glucose 4.84 mmol/L.
- Day 354 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 4.78 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 446 (ECOG 1): M Protein 2.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.116 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.8 mg/dL; Immunoglobulin G 3.47 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 5.55 µkat/L; Hemoglobin 3.91 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 34 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.58 mmol/L; Albumin 40 g/L; Total Protein 8.7 g/dL; Glucose 6.71 mmol/L.

Other clinical attributes
- Day -2: Weight: 86 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2574_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2574_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
